Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6XA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6XA-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localization: L frontal

Diagnosis: Oligoastrocytoma (grade II WHO)

Name of Pathologist:

ICD-O-3
Oligoastrocytoma, grade II
9382/3

Site Brain, supratentorial lvs
C71.0

QW 8/12/13

Diagnosis Discrepancy	lw 7/9/13	☒
TIPTAA Discrepancy		☒

Source: NCI Genomic Data Commons file 27818557-00f7-41ce-8aa1-b1cd4243d143 (TCGA-QH-A6XA.9B2B37D4-EF00-4EC5-A549-FADFA7B45BD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).